Somatic mutation profile of tumor specimen TCGA-49-6761-01A (aliquot TCGA-49-6761-01A-31D-1945-08) from TCGA case TCGA-49-6761, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.0 years (24,849 days).
Specimen TCGA-49-6761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49148ac1-b4d7-45f2-a6ff-46cf3fd82c5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6761-11A (Solid Tissue Normal), aliquot TCGA-49-6761-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5405e8df-5f13-4c92-bdcc-d7a7a81c3911

The open-access MAF lists 192 somatic variants for this specimen: 143 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 46, Nonsense Mutation 13, Splice Site 5, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs1085307422, CM044558, COSV66359525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.477+1G>T p.X159_splice | Splice Site (SNP) | VAF 8/43 reads (19%) | catalogued as COSV61014922; called by muse, varscan2
- ACSM2A | c.1629+1G>T p.X543_splice (on ENST00000219054; = p.X464_splice on NM_001308169.2) | Splice Site (SNP) | VAF 22/154 reads (14%) | catalogued as COSV54582086; called by muse, mutect2, varscan2
- ADAMTS9 | c.3725G>T p.W1242L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55774798; called by muse, mutect2, varscan2
- ADARB2 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV67217398; called by muse, mutect2, varscan2
- ADGRB3 | c.1756G>T p.G586W | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356361440, COSV65382186, COSV65406157; called by muse, mutect2, varscan2
- ADGRB3 | c.4205A>G p.E1402G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV53234316; called by muse, mutect2, varscan2
- ADGRL2 | c.1678A>C p.S560R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV54651715; called by muse, mutect2, varscan2
- AKAP6 | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV55204693; called by muse, mutect2
- ALS2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs374117082; called by muse, mutect2, varscan2
- ANGPT1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV52430436; called by muse, mutect2, varscan2
- AZI2 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs1490739686, COSV99843520; called by muse, mutect2, varscan2
- BRWD3 | c.5256A>T p.Q1752H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV64743837; called by muse, mutect2, varscan2
- BTN3A3 | c.424A>T p.K142* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as COSV55070842; called by muse, mutect2, varscan2
- C6 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.106); catalogued as COSV54704752; called by muse, mutect2, varscan2
- C7 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57470710; called by muse, mutect2, varscan2
- CAMSAP2 | c.1509A>G p.I503M (on ENST00000236925 / NM_001297707.2; = p.I492M on NM_203459.3) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1447912522, COSV52666745; called by muse, mutect2, varscan2
- CAPN13 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.673); catalogued as COSV54428322; called by muse, mutect2
- CASZ1 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100680812, COSV59731868; called by muse, varscan2
- CCDC186 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV65159272; called by muse, mutect2, varscan2
- CCDC77 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV53471862; called by muse, mutect2, varscan2
- CCT6A | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs368822326, COSV51904381; called by muse, mutect2
- CER1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66602902; called by muse, mutect2, varscan2
- CHD6 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as COSV58553708; called by muse, mutect2, varscan2
- CLK2 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373922154; called by muse, varscan2
- CNGA2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1301502750, COSV61703126; called by muse, mutect2, varscan2
- CNTNAP5 | c.1884C>G p.I628M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV70471912; called by muse, mutect2, varscan2
- COL11A1 | c.1999-1G>A p.X667_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV62172611, COSV62179077, COSV62198366; called by muse, mutect2, varscan2
- COL15A1 | c.2878C>A p.P960T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV66641265; called by mutect2, varscan2
- COL28A1 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68080475; called by muse, mutect2, varscan2
- COL5A2 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66407002; called by muse, mutect2, varscan2
- CSMD3 | c.5124G>T p.M1708I (on ENST00000297405 / NM_001363185.1; = p.M1604I on NM_052900.3) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs866818702, COSV52100363; called by muse, mutect2, varscan2
- CUX2 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs927215294, COSV55624141, COSV55643467; called by muse, mutect2, varscan2
- CYP11B2 | c.591A>G p.I197M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as rs886062744, COSV59994405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2A13 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201061612, COSV57836327; called by muse, mutect2, varscan2
- DCAF12L2 | c.1107T>A p.H369Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63580199; called by muse, mutect2, varscan2
- DCAF15 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs767785346, COSV54335060; called by muse, mutect2, varscan2
- DDX50 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs759074528, COSV65291687; called by muse, mutect2, varscan2
- DGKK | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65706314; called by muse, mutect2, varscan2
- DLG5 | c.5649C>A p.Y1883* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV64946675; called by muse, mutect2, varscan2
- DNAH5 | c.13720A>C p.N4574H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV54203479; called by muse, mutect2, varscan2
- DNAH9 | c.5756G>T p.G1919V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52333612; called by muse, mutect2, varscan2
- DOCK4 | c.5596G>A p.E1866K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV70233334; called by muse, mutect2, varscan2
- DPF2 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV52887829; called by muse, mutect2, varscan2
- EIF3M | c.314+1G>A p.X105_splice | Splice Site (SNP) | VAF 24/100 reads (24%) | catalogued as COSV60072305; called by muse, mutect2, varscan2
- ELAVL2 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV56357233; called by muse, mutect2, varscan2
- ENPP2 | c.2449G>A p.E817K (on ENST00000075322 / NM_001040092.3; = p.E869K on NM_006209.5) | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50009935; called by muse, mutect2
- EPHA6 | c.2470C>A p.P824T (on ENST00000389672 / NM_001080448.3; = p.P216T on NM_173655.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.763); catalogued as COSV67558449, COSV67576518; called by muse, mutect2, varscan2
- EPPK1 | c.6035C>T p.A2012V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360747826, COSV73260792, COSV73260902; called by muse, mutect2, varscan2
- ERV3-1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99275316; called by muse, mutect2
- F13A1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1173364213, COSV53553174; called by muse, mutect2, varscan2
- FAT1 | c.11708G>C p.S3903T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV71671885; called by muse, mutect2, varscan2
- FER | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55282789; called by muse, mutect2, varscan2
- FIGN | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60762909; called by muse, mutect2, varscan2
- FIGN | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60762919; called by muse, mutect2, varscan2
- FNBP4 | c.1691G>C p.R564P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55445891; called by muse, mutect2
- GALNT15 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV60215252; called by muse, mutect2, varscan2
- GGT6 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as rs1362149483, COSV54593044; called by muse, mutect2, varscan2
- GTF2E1 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV52203127; called by muse, mutect2, varscan2
- IGHV3-20 | c.147T>G p.D49E | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs181860901; called by muse, mutect2, varscan2
- ITGAL | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs890462581, COSV63320004; called by muse, mutect2, varscan2
- KCNH8 | c.2911C>T p.Q971* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as rs779834044, COSV60456302; called by muse, mutect2, varscan2
- KIAA1109 | c.13196C>T p.P4399L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747219436, COSV52662128; called by muse, mutect2, varscan2
- KRT80 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as rs774487570, COSV100502588, COSV57547454, COSV57551231; called by muse, mutect2, varscan2
- LAMC2 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV51452268; called by muse, mutect2
- LCMT2 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59789443; called by muse, mutect2, varscan2
- LILRB2 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV58743453, COSV58745032; called by muse, mutect2
- LRRC49 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV53007830; called by muse, mutect2, varscan2
- MAP2K3 | c.538C>G p.L180V (on ENST00000342679 / NM_145109.3; = p.L151V on NM_002756.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57561749; called by muse, mutect2
- MCHR2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407048873, COSV55999417; called by muse, mutect2, varscan2
- MCTP1 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV56503691; called by muse, mutect2, varscan2
- MED16 | c.1868A>T p.D623V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54123012; called by muse, mutect2, varscan2
- MET | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100577374, COSV59256697; called by muse, mutect2, varscan2
- MINDY2 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57505189; called by muse, mutect2, varscan2
- MUC4 | c.13141C>T p.P4381S (on ENST00000463781 / NM_018406.7; = p.P145S on NM_004532.6) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV100204026; called by muse, mutect2, varscan2
- MUC4 | c.13140C>G p.N4380K (on ENST00000463781 / NM_018406.7; = p.N144K on NM_004532.6) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV100204028; called by muse, mutect2, varscan2
- MYH2 | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV55431418, COSV55440594; called by muse, mutect2, varscan2
- MYO3A | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV56319430; called by muse, mutect2
- NAV3 | c.738T>A p.T246= | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99888195; called by muse, mutect2, varscan2
- NEURL1 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV63507779; called by muse, mutect2, varscan2
- NKAPL | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV59196921; called by muse, mutect2, varscan2
- NRG3 | c.1664C>T p.S555F (on ENST00000404547 / NM_001370084.1; = p.S531F on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.568); catalogued as rs150723859, COSV64544965; called by muse, mutect2, varscan2
- OR4D2 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV73459695; called by muse, mutect2, varscan2
- OSBPL8 | c.2147C>G p.A716G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53877911; called by muse, mutect2, varscan2
- OSR1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV55344607; called by muse, mutect2, varscan2
- PAPPA2 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.315); catalogued as COSV62772687; called by muse, mutect2, varscan2
- PBXIP1 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs372206354; called by muse, mutect2, varscan2
- PCDH15 | c.2757G>A p.M919I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57262122; called by muse, mutect2, varscan2
- PCDH7 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202059640, COSV100688435, COSV62336477; called by muse, mutect2, varscan2
- PCDHA3 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs782192647, COSV63538755; called by muse, mutect2
- PCDHB16 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53357576; called by muse, mutect2, varscan2
- PCSK5 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1290957880, COSV65083440; called by muse, mutect2, varscan2
- PLCB4 | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53792899; called by muse, mutect2, varscan2
- PLEKHA7 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63043548; called by muse, mutect2
- PLSCR1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV61012243; called by mutect2, varscan2
- PPM1A | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as rs143557303; called by muse, mutect2, varscan2
- REG3G | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV55448198; called by muse, mutect2, varscan2
- RGS9 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52222919; called by muse, mutect2, varscan2
- RIPOR2 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as rs1442990124, COSV52417109; called by muse, mutect2, varscan2
- RNASEH1 | c.649+1G>C p.X217_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as COSV59437986; called by muse, mutect2
- RNF216 | c.1471G>A p.E491K (on ENST00000425013 / NM_207116.3; = p.E548K on NM_207111.4) | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV66288984; called by muse, mutect2
- RP1L1 | c.2309C>A p.T770K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs151054713, COSV66751590; called by muse, mutect2, varscan2
- SAMD3 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs17852709, COSV60774002; called by mutect2, varscan2
- SAMD9L | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV59079381; called by muse, mutect2, varscan2
- SBNO2 | c.2234A>T p.Q745L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV62318624, COSV62320204; called by muse, mutect2, varscan2
- SCAF8 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV65789945; called by muse, mutect2, varscan2
- SCN11A | c.4490T>A p.L1497Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56565550; called by mutect2, varscan2
- SEMA3D | c.2209A>T p.R737W | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV52387220, COSV52398669; called by muse, mutect2
- SHANK2 | c.4210G>T p.D1404Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53585422; called by muse, mutect2, varscan2
- SNW1 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55053017; called by muse, mutect2, varscan2
- SPANXN2 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 125/659 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV65127674, COSV65128871; called by muse, varscan2
- SPAST | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV59512608; called by muse, mutect2
- SPRED1 | c.1053A>C p.K351N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV54434207; called by muse, mutect2
- SRF | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV52725139; called by muse, mutect2, varscan2
- SSR3 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs983523875, COSV54019953; called by muse, mutect2, varscan2
- STAU1 | c.499G>T p.E167* (on ENST00000371856 / NM_001319135.1; = p.E86* on NM_004602.3) | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV61458831; called by muse, mutect2, varscan2
- STX5 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs779963977, COSV53678017; called by muse, varscan2
- STXBP5L | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56499607; called by muse, mutect2, varscan2
- TAF4 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV53334358; called by muse, varscan2
- TIFA | c.428dup p.L143Ffs*39 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs1302572317; called by mutect2, pindel, varscan2
- TTN | c.74613C>G p.I24871M (on ENST00000591111; = p.I17447M on NM_003319.4) | Missense Mutation (SNP) | VAF 31/262 reads (12%) | PolyPhen possibly damaging (0.79); catalogued as COSV59883121, COSV60193603, COSV60309938; called by muse, mutect2, varscan2
- TTN | c.66290A>T p.E22097V (on ENST00000591111; = p.E14673V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | PolyPhen possibly damaging (0.848); catalogued as COSV59883151; called by mutect2, varscan2
- TUBB8 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV59114614; called by muse, mutect2, varscan2
- UBE3A | c.2362A>T p.R788W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51660994; called by mutect2, varscan2
- VAMP4 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV52560403; called by muse, mutect2
- WNT7A | c.202A>C p.M68L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV53196714; called by muse, mutect2
- YEATS4 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56088031; called by muse, mutect2, varscan2
- ZFP82 | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67564569, COSV67565461; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56271679; called by muse, mutect2, varscan2
- ZNF132 | c.1518G>C p.Q506H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs766018632, COSV54234060; called by muse, mutect2, varscan2
- ZNF445 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV68538402; called by muse, mutect2, varscan2
- ZNF518B | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs765665207, COSV58721278; called by muse, mutect2, varscan2
- ZNF676 | c.1111T>A p.C371S (on ENST00000650058; = p.C339S on NM_001001411.3) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68092128; called by muse, mutect2, varscan2
- ZNF761 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61887598; called by muse, mutect2, varscan2
- ZNF761 | c.1616G>C p.C539S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.241); catalogued as COSV61887604; called by muse, mutect2, varscan2
- APC | c.6676_6677del p.G2227Qfs*12 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- DDX56 | c.943del p.T315Lfs*35 | Frame Shift Del (DEL) | VAF 86/213 reads (40%) | called by mutect2, pindel, varscan2
- ESR2 | c.611_646del p.C204_K216delins* | Nonsense Mutation (DEL) | VAF 35/172 reads (20%) | called by mutect2, pindel
- FCGBP | c.10151C>G p.S3384* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- IGKV1-12 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGLV2-33 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- KIR3DL2 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC6 | c.2661del p.K888Sfs*22 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- ADARB2 | c.471G>A p.A157= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs551013892, COSV101186736; called by mutect2, varscan2
- ALMS1 | c.12315G>A p.Q4105= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV52502499; called by muse, mutect2, varscan2
- ARPP21 | c.1029G>A p.G343= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV51791925; called by muse, varscan2
- ASXL3 | c.1113G>A p.K371= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs202108426, COSV52456973, COSV52474025; called by muse, mutect2, varscan2
- ATP10B | c.4203G>A p.Q1401= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs1399500822, COSV59143591, COSV59159063; called by muse, mutect2, varscan2
- BAG6 | c.3144A>G p.T1048= (on ENST00000676571; = p.T1001= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as COSV52987899; called by muse, mutect2, varscan2
- CHERP | c.1974C>T p.L658= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs181968256; called by mutect2, varscan2
- CIAPIN1 | c.195A>T p.S65= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as COSV67953199; called by muse, mutect2, varscan2
- COL1A2 | c.2625C>T p.L875= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV51952733; called by muse, mutect2, varscan2
- CYP26B1 | c.937C>T p.L313= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV50010700; called by muse, mutect2
- DNAH10 | c.1722C>T p.V574= (on ENST00000409039; = p.V513= on NM_207437.3) | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV68987734; called by muse, mutect2, varscan2
- EYS | c.108C>A p.P36= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs1014843963, COSV60976139; called by muse, mutect2, varscan2
- EZR | c.456G>A p.L152= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV61452588; called by muse, mutect2, varscan2
- GCNT2 | c.513G>A p.L171= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV65456442; called by muse, mutect2, varscan2
- GIPC3 | c.381G>A p.T127= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs766652884, COSV100461202; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL1RAPL1 | c.537C>A p.I179= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs372833369, COSV56237352, COSV56238345; called by muse, mutect2, varscan2
- KIF13A | c.1206G>A p.L402= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs755082662, COSV52442557; called by mutect2, varscan2
- KIF16B | c.390C>T p.F130= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV61701154; called by mutect2, varscan2
- LRP1B | c.4023A>T p.T1341= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV67185361; called by muse, mutect2, varscan2
- LRP1B | c.2097T>C p.G699= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV67185365; called by muse, mutect2, varscan2
- MAGEB16 | c.87G>A p.Q29= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV67873530; called by muse, mutect2, varscan2
- MAN2A1 | c.1848T>G p.S616= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV54846199; called by muse, mutect2
- MRPS18A | c.135G>A p.K45= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV64521801; called by muse, mutect2, varscan2
- MTPAP | c.796C>T p.L266= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV53931371; called by muse, varscan2
- MYH15 | c.915A>G p.G305= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1351988881, COSV56304247; called by muse, mutect2, varscan2
- OR13G1 | c.162G>T p.T54= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV62943288, COSV62943347; called by muse, mutect2, varscan2
- OR4C16 | c.297C>A p.V99= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as rs1554964837, COSV58940578; called by muse, mutect2, varscan2
- PAN2 | c.3501C>T p.L1167= (on ENST00000425394 / NM_001127460.3; = p.L1163= on NM_014871.5) | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV56263828; called by muse, mutect2, varscan2
- PCDHA9 | c.2076G>T p.T692= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs549105939, COSV65323311; called by muse, mutect2, varscan2
- PCLO | c.528T>C p.F176= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV61615431; called by muse, varscan2
- POLR3B | c.2526A>T p.G842= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV57275845; called by mutect2, varscan2
- PPP3R2 | c.285G>A p.A95= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs971779491, COSV100701928, COSV62450522; called by muse, mutect2, varscan2
- PSG5 | c.774C>T p.Y258= | Silent (SNP) | VAF 60/398 reads (15%) | catalogued as rs1420239197, COSV61653449; called by muse, varscan2
- PTK2B | c.273G>T p.G91= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV57749856; called by mutect2, varscan2
- RAG1 | c.2923C>A p.R975= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as CM081767, COSV55023875, COSV55024947; called by muse, mutect2, varscan2
- SAMD8 | c.51A>G p.V17= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV65509072; called by muse, varscan2
- SCN10A | c.4734C>A p.A1578= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV71860203, COSV71862381; called by muse, mutect2, varscan2
- SCNN1B | c.165C>T p.L55= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100225495; called by mutect2, varscan2
- SLC17A7 | c.1329C>T p.G443= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1324748733, COSV55546386; called by mutect2, varscan2
- SLC34A2 | c.1107C>G p.L369= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV65940575; called by muse, mutect2
- SLC47A1 | c.1197G>A p.L399= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as COSV54498840; called by muse, mutect2, varscan2
- SLITRK2 | c.1545G>C p.L515= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV59422978; called by muse, mutect2, varscan2
- SPTBN2 | c.5109G>A p.L1703= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV59446518; called by muse, mutect2, varscan2
- SYNE2 | c.3861G>A p.K1287= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV59939395; called by muse, mutect2, varscan2
- TBL1X | c.816C>A p.L272= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV54274462; called by muse, mutect2, varscan2
- TCF20 | c.726C>T p.S242= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs749970857, COSV59488225; called by muse, mutect2
- DCX | c.-22-545C>T | Intron (SNP) | VAF 13/98 reads (13%) | catalogued as COSV57565847; called by muse, mutect2, varscan2
- KITLG | c.130-2188G>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99933200; called by mutect2, varscan2
- LINC00922 | n.873C>T | RNA (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
